Gene-level copy-number profile of tumor specimen ALCH-B0AH-TTP1-A from ALCHEMIST case ALCH-B0AH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.3 years (23,125 days).
Specimen ALCH-B0AH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c96d4458-3e2b-45a5-9ab1-7100d111b4db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/f38f8ebc-f5a5-4064-a15b-c3c47999c8ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 7,229; copy number 2: 50,253; copy number 3: 777; copy number 4: 482; copy number 5: 3; copy number 6: 4; copy number 7: 45.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,425,980–2,505,532, 3 genes: PLCH2, AL139246.1, AL139246.4.
- chr1:3,778,559–3,796,498, 3 genes: LRRC47, RN7SL574P, AL365330.1.
- chr1:15,720,312–15,741,392, 2 genes (within-gene range 0–2): AL450998.2, SLC25A34.
- chr1:36,080,066–36,125,222, 4 genes: AL138787.1, TEKT2, ADPRS, COL8A2.
- chr2:119,169,822–119,170,115, 1 gene: RN7SL468P.
- chr2:127,048,027–127,107,288, 1 gene: BIN1.
- chr2:130,139,287–130,145,134, 1 gene (within-gene range 0–2): CCDC74B.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–3): NRBF2P6, ECEL1P3.
- chr4:3,441,968–3,501,473, 2 genes: HGFAC, DOK7.
- chr5:69,068,925–69,069,200, 1 gene: SUMO2P4.
- chr5:177,379,235–177,479,656, 8 genes: SLC34A1, PFN3, F12, GRK6, PRR7-AS1, PRR7, DBN1, AC145098.2.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr6:73,241,314–73,395,133, 12 genes (within-gene range 0–2): KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8.
- chr7:45,816,216–45,821,064, 3 genes: CICP20, AC096582.1, AC096582.2.
- chr7:130,380,339–130,388,114, 1 gene: CPA1.
- chr7:159,006,522–159,030,195, 1 gene (within-gene range 0–2): LINC00689.
- chr10:86,668,507–86,736,072, 1 gene: LDB3.
- chr10:92,418,667–92,420,875, 1 gene: MARK2P9.
- chr12:57,194,504–57,226,449, 2 genes (within-gene range 0–2): MIR1228, NXPH4.
- chr15:22,160,431–22,225,329, 6 genes: IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3, MIR1268A.
- chr15:25,172,635–25,187,616, 9 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10.
- chr15:25,204,357–25,225,284, 12 genes (within-gene range 0–2): SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:75,228,181–75,268,053, 2 genes (within-gene range 0–2): BCAR1, AC009078.3.
- chr17:6,417,685–6,418,264, 1 gene (within-gene range 0–2): AC055872.1.
- chr17:42,101,404–42,112,714, 1 gene: DHX58.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,924,181–48,314,224, 1 gene, copy number 7 (within-gene range 4–7): AC092650.1.
- chr2:47,989,625–49,451,896, 20 genes, copy number 6–7: VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P.
- chr16:2,513,952–2,772,538, 26 genes, copy number 7 (within-gene range 2–7): ATP6V0C, AC093525.1, AC093525.8, AMDHD2, CEMP1, MIR3178, PDPK1, AC093525.6, AC093525.5, AC093525.7, AC093525.4, AC093525.3, AC093525.9, AC093525.10, AC141586.5, AC141586.3, AC141586.1, PDPK2P, AC141586.4, AC141586.2, ERVK13-1, KCTD5, AC092117.2, PRSS27, SRRM2-AS1, SRRM2.
- chr16:2,852,730–2,859,726, 2 genes, copy number 6: PRSS22, AC003965.2.
- chr22:20,314,238–20,321,203, 3 genes, copy number 5: DGCR6L, AC007663.4, AC007663.3.

Autosomal genes at a single copy (total copy number 1): 4,390. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
